Somatic mutation profile of tumor specimen MMRF_1324_1_BM_CD138pos (aliquot MMRF_1324_1_BM_CD138pos_T1_KAS5U_L01605) from MMRF case MMRF_1324, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.7 years (22,526 days).
Specimen MMRF_1324_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b2206df-4d33-41ef-a76c-ad4d9e42fb5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1324_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1324_1_PB_Whole_C2_KAS5U_L01614; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cf996cd-7429-4fa9-856e-76a851708b73

The open-access MAF lists 78 somatic variants for this specimen: 32 protein-altering or splice-affecting, 9 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, 3'UTR 25, Silent 9, Intron 4, 5'UTR 4, Nonsense Mutation 3, 3'Flank 2, Frame Shift Del 1, Splice Site 1, Splice Region 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL4 | c.635C>A p.T212N | Missense Mutation (SNP) | VAF 246/384 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as rs756937513; called by muse, mutect2, varscan2
- BMS1 | c.958C>A p.P320T | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1377513103; called by muse, mutect2, varscan2
- BZW2 | c.340-2A>G p.X114_splice | Splice Site (SNP) | VAF 31/77 reads (40%) | catalogued as COSV51756484; called by muse, mutect2, varscan2
- CEL | c.991G>A p.A331T (on ENST00000673714; = p.A328T on NM_001807.6) | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.519); catalogued as rs757669397; called by muse, mutect2, varscan2
- CEP120 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV60265960; called by muse, mutect2, varscan2
- CYP11B1 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 112/202 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs139569725; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- H1-5 | c.252G>C p.K84N | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as rs754859751; called by muse, mutect2, varscan2
- IGHV2-70 | c.228T>G p.D76E | Missense Mutation (SNP) | VAF 71/76 reads (93%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs373802343; called by muse, varscan2
- IGHV2-70 | c.153T>A p.S51R | Missense Mutation (SNP) | VAF 54/56 reads (96%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs368987043; called by muse, varscan2
- IGLV2-14 | c.60G>C p.Q20H | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as rs770123418; called by muse, mutect2, varscan2
- IP6K1 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 116/196 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57695771; called by muse, mutect2, varscan2
- MOB1A | c.319A>G p.I107V | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs954568506; called by muse, mutect2, varscan2
- MRPL38 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 46/87 reads (53%) | catalogued as COSV53933289; called by muse, mutect2, varscan2
- NOL6 | c.2526C>T p.H842= | Splice Region (SNP) | VAF 47/98 reads (48%) | catalogued as rs749219176; called by muse, mutect2, varscan2
- SLC16A12 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371779195; called by muse, mutect2, varscan2
- TRIM17 | c.905C>G p.T302S | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1182339014; called by muse, mutect2, varscan2
- CALCRL | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 86/174 reads (49%) | called by muse, mutect2, varscan2
- CBX1 | c.179G>A p.C60Y | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COL6A6 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 180/283 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- FSCN2 | c.52A>T p.N18Y | Missense Mutation (SNP) | VAF 69/131 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSCN2 | c.53A>C p.N18T | Missense Mutation (SNP) | VAF 68/130 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- H3C10 | c.240G>C p.K80N | Missense Mutation (SNP) | VAF 75/150 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- INPP4A | c.2651G>A p.C884Y (on ENST00000074304 / NM_001134224.1; = p.C845Y on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LUZP4 | c.113A>G p.E38G | Missense Mutation (SNP) | VAF 24/25 reads (96%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NID2 | c.2987C>T p.T996I | Missense Mutation (SNP) | VAF 69/69 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- PLCB1 | c.163A>G p.T55A | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- SLCO1C1 | c.910A>C p.S304R | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SP140 | c.1704_1705del p.R569Sfs*12 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, varscan2
- TDRD6 | c.3061C>T p.Q1021* | Nonsense Mutation (SNP) | VAF 92/170 reads (54%) | called by muse, mutect2, varscan2
- TLR3 | c.2078C>T p.T693I | Missense Mutation (SNP) | VAF 133/317 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF480 | c.1406C>T p.S469L | Missense Mutation (SNP) | VAF 13/411 reads (3%) | SIFT tolerated (0.49); PolyPhen benign (0.388); called by muse, mutect2
- ZNF765 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 145/287 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ACVR1 | c.1296C>T p.Y432= | Silent (SNP) | VAF 97/204 reads (48%) | catalogued as rs201131823; called by muse, mutect2, varscan2
- BCL9 | c.1830C>A p.G610= | Silent (SNP) | VAF 212/309 reads (69%) | called by muse, mutect2, varscan2
- COL21A1 | c.2307T>G p.P769= | Silent (SNP) | VAF 54/123 reads (44%) | called by muse, mutect2, varscan2
- FERMT2 | c.72G>A p.V24= | Silent (SNP) | VAF 129/134 reads (96%) | called by muse, mutect2, varscan2
- IGKV4-1 | c.243A>G p.E81= | Silent (SNP) | VAF 52/53 reads (98%) | catalogued as rs369161039; called by muse, mutect2, varscan2
- LPCAT2 | c.222G>A p.A74= | Silent (SNP) | VAF 55/125 reads (44%) | catalogued as rs151001955; called by muse, mutect2, varscan2
- MAGEL2 | c.96C>G p.A32= | Silent (SNP) | VAF 56/100 reads (56%) | catalogued as rs1233026259; called by muse, mutect2, varscan2
- SHANK2 | c.5085C>T p.P1695= | Silent (SNP) | VAF 74/160 reads (46%) | catalogued as COSV53594561; called by muse, mutect2, varscan2
- TLR2 | c.786C>T p.T262= | Silent (SNP) | VAF 59/123 reads (48%) | catalogued as rs202008414, COSV99472077; called by muse, mutect2, varscan2
- ABCC13 | n.3427C>A | RNA (SNP) | VAF 32/46 reads (70%) | called by muse, mutect2, varscan2
- ANK2 | c.*1906G>A | 3'UTR (SNP) | VAF 49/89 reads (55%) | catalogued as rs1461535852; called by muse, mutect2, varscan2
- CACNA1E | c.*8330C>T | 3'UTR (SNP) | VAF 42/134 reads (31%) | called by muse, mutect2, varscan2
- CHST15 | c.*169G>A | 3'UTR (SNP) | VAF 18/41 reads (44%) | catalogued as rs548460895; called by muse, mutect2, varscan2
- COLCA2 | chr11:111294227 A>G | 5'Flank (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- COMMD9 | chr11:36270083 A>C | 3'Flank (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- CUBN | c.*112del | 3'UTR (DEL) | VAF 74/222 reads (33%) | called by mutect2, pindel, varscan2
- DDX6 | chr11:118751944 del T | 3'Flank (DEL) | VAF 40/98 reads (41%) | called by mutect2, pindel, varscan2
- FSTL5 | c.*973C>G | 3'UTR (SNP) | VAF 88/179 reads (49%) | called by muse, mutect2, varscan2
- FSTL5 | c.*972C>G | 3'UTR (SNP) | VAF 88/179 reads (49%) | called by muse, mutect2, varscan2
- FZD3 | c.*10890A>T | 3'UTR (SNP) | VAF 52/85 reads (61%) | called by muse, mutect2, varscan2
- GATD1 | c.*2205G>A | 3'UTR (SNP) | VAF 16/36 reads (44%) | catalogued as rs943730231; called by muse, mutect2, varscan2
- GOLM1 | c.*610A>T | 3'UTR (SNP) | VAF 52/122 reads (43%) | called by muse, mutect2, varscan2
- GOLM1 | c.*609A>G | 3'UTR (SNP) | VAF 53/122 reads (43%) | called by muse, mutect2, varscan2
- ITK | c.*2492A>C | 3'UTR (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- LTB | c.163-36A>T | Intron (SNP) | VAF 221/473 reads (47%) | catalogued as rs139528542, COSV53000823; called by muse, varscan2
- LTB | c.163-96A>G | Intron (SNP) | VAF 180/390 reads (46%) | catalogued as rs541371875; called by muse, varscan2
- MAD2L1 | c.*367G>A | 3'UTR (SNP) | VAF 87/181 reads (48%) | called by muse, mutect2, varscan2
- MED20 | c.*865_*866del | 3'UTR (DEL) | VAF 32/67 reads (48%) | called by mutect2, varscan2
- MORC2 | c.-66A>C | 5'UTR (SNP) | VAF 158/305 reads (52%) | called by muse, mutect2, varscan2
- PAIP2B | c.*3748G>A | 3'UTR (SNP) | VAF 167/439 reads (38%) | called by muse, mutect2, varscan2
- PAM | c.*1317C>T | 3'UTR (SNP) | VAF 72/144 reads (50%) | called by muse, mutect2, varscan2
- PCDHAC1 | c.*981A>C | 3'UTR (SNP) | VAF 54/118 reads (46%) | called by muse, varscan2
- POGLUT3 | c.*2449G>A | 3'UTR (SNP) | VAF 138/271 reads (51%) | catalogued as rs1011207407; called by muse, mutect2, varscan2
- PRR16 | c.*28dup | 3'UTR (INS) | VAF 70/428 reads (16%) | catalogued as rs1261171637; called by mutect2, varscan2
- RAB11FIP4 | c.*6249dup | 3'UTR (INS) | VAF 61/150 reads (41%) | called by mutect2, pindel, varscan2
- RARG | c.*977C>T | 3'UTR (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- RNF157 | c.-69G>A | 5'UTR (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- SCN5A | c.*1718G>A | 3'UTR (SNP) | VAF 50/146 reads (34%) | called by muse, mutect2, varscan2
- SERPINB6 | c.370-55C>T | Intron (SNP) | VAF 84/159 reads (53%) | catalogued as rs1038654317; called by muse, mutect2, varscan2
- SHPK | c.*882C>T | 3'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- SLC17A9 | c.629-32T>C | Intron (SNP) | VAF 201/409 reads (49%) | called by muse, mutect2, varscan2
- SLC39A8 | c.*681C>T | 3'UTR (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- SPTLC2 | c.*5544C>A | 3'UTR (SNP) | VAF 42/42 reads (100%) | called by muse, varscan2
- SPTLC2 | c.*5386T>C | 3'UTR (SNP) | VAF 48/48 reads (100%) | called by muse, varscan2
- UGCG | c.-28G>C | 5'UTR (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- ZNF558 | c.-112G>A | 5'UTR (SNP) | VAF 47/94 reads (50%) | catalogued as rs1161189132; called by muse, mutect2, varscan2
